Somatic mutation profile of tumor specimen TCGA-KS-A4IB-01A (aliquot TCGA-KS-A4IB-01A-11D-A257-08) from TCGA case TCGA-KS-A4IB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.5 years (15,157 days).
Specimen TCGA-KS-A4IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdce36df-8e9c-4180-9b1f-da0dbd8eb964.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4IB-11A (Solid Tissue Normal), aliquot TCGA-KS-A4IB-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2881a402-ed5b-4278-b836-84cce87cfa89

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.558C>G p.H186Q (on ENST00000382580 / NM_001005735.2; = p.H143Q on NM_007194.4) | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1555927151, COSV60423639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.3583G>T p.V1195L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52908571; called by muse, mutect2, varscan2
- DNAH9 | c.7925C>T p.A2642V | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs750150972, COSV52346119; called by muse, mutect2, varscan2
- FCRL2 | c.1438A>G p.M480V | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63834440; called by muse, mutect2, varscan2
- HIF1A | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60190547; called by muse, mutect2, varscan2
- LRRC49 | c.1170-2A>G p.X390_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV53013342; called by muse, mutect2
- NIPA1 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.193); catalogued as COSV61680417; called by muse, mutect2, varscan2
- NSUN6 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | catalogued as COSV66034402; called by muse, mutect2, varscan2
- PDE4B | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs769931436, COSV58464273; called by muse, mutect2, varscan2
- TFR2 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56155549; called by muse, mutect2, varscan2
- TTPA | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs368391591; called by muse, mutect2, varscan2
- ZNF275 | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs1207719754, COSV64705051; called by muse, mutect2, varscan2
- UBA7 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BSN | c.4767C>G p.P1589= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1415747604, COSV56523730; called by muse, mutect2, varscan2
- RET | c.960C>T p.P320= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs756761746, COSV60686128; called by muse, mutect2, varscan2
